Surgical pathology report (de-identified scan), TCGA case TCGA-J2-8194, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-J2-8194-01A (Primary Tumor).

[page 1 of 7]
MRN

Name

Encounter Number

COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected

Time Reported

Ordering Provider

Status

Time Received

Order Number

Results

Correction

Source of Specimen

- A. 4R #1 - FS-
- B. 4R #2 - FS-
- C. 4R #3 - FS-
- D. STATION 10 - FS-
- E. STATION 7 - FS-
- F. WEDGE RESECTION RIGHT UPPER LOBE-
- G. WEDGE RESECTION RIGHT UPPER LOBE - FS-
- H. STATION 9 #1 - FS-
- I. STATION 9 #2 - FS-
- J. STATION 7 #3 - NFS-
- K. RIGHT LOWER LOBE-
- L. RIGHT LOWER LOBE MASS- FS
- M. STATION 7 #2- FS
- N. TISSUE ON PLEURAL SURFACE ABUTTING MIDDLE LOBE FS-

FINAL DIAGNOSIS:

- A. 4R #1 - FS-
LYMPH NODE, NO TUMOR SEEN.
- B. 4R #2 - FS-
LYMPH NODE, NO TUMOR SEEN.
- C. 4R #3 - FS-
LYMPH NODE, NO TUMOR SEEN.
- D. STATION 10 - FS-
LYMPH NODE, NO TUMOR SEEN.
- E. STATION 7 - FS-
LYMPH NODE, NO TUMOR SEEN.
- F. WEDGE RESECTION RIGHT UPPER LOBE-
LUNG WITH APICAL ELASTOTIC SCAR

[page 2 of 7]
NO TUMOR SEEN.

G. WEDGE RESECTION RIGHT UPPER LOBE - FS-
SEE PART F.

H. STATION 9 #1 - FS-
LYMPH NODE, NO TUMOR SEEN.

I. STATION 9 #2 - FS-
LYMPH NODE, NO TUMOR SEEN.

J. STATION 7 #3 - NFS-
LYMPH NODE, NO TUMOR SEEN.

K. RIGHT LOWER LOBE-
INVASIVE CARCINOMA.

HISTOLOGIC TYPE: ADENOCARCINOMA WITH EXTENSIVE PAPILLARY /
BRONCHOALVEOLAR ("LEPIDIC") PATTERN.

HISTOLOGIC GRADE: 1/4.

TUMOR FOCALITY: UNIFOVAL.

TUMOR SIZE: 4 CM.

TUMOR SITE: RIGHT LOWER LOBE.

THE TUMOR INVADES THROUGH THE VISCERAL PLEURA AND INVOLVES THE
SUPERFICIAL DIAPHRAGMATIC SOFT TISSUE.

ATELECTASIS/OBSTRUCTIVE PNEUMONITIS EXTENDING TO HILUM: NOT
SEEN.

LYMPHATIC (SMALL VESSEL) INVASION: NOT SEEN.

LARGE VESSEL INVASION: NOT SEEN.

ONE HILAR LYMPH NODE, NO TUMOR SEEN.

LYMPH NODES INCLUDED IN ALL PARTS: NUMBER INVOLVED : 0
NUMBER EXAMINED: 10

TNM STAGE: pT3, pN0, pMX.

SPECIMEN TYPE: RIGHT LOWER LOBECTOMY.

NO TUMOR SEEN AT RESECTION MARGINS.

L. RIGHT LOWER LOBE MASS- FS
SEE PART K.

M. STATION 7 #2- FS
LYMPH NODE, NO TUMOR SEEN.

N. TISSUE ON PLEURAL SURFACE ABUTTING MIDDLE LOBE FS-
REACTIVE PLEURITIS AND SCAR.

Prepare

[page 3 of 7]
NO TUMOR SEEN.

Signed Others

Frozen Section

A. 4R #1- NO TUMOR SEEN.

4R #2- NO TUMOR SEEN.

4R #3- NO TUMOR SEEN.

STATION 10- NO TUMOR SEEN.

STATION 7- EXTREMELY SCANT LYMPHOID TISSUE, NO TUMOR SEEN.

WEDGE RESECTION OF RIGHT UPPER LOBE- NO GROSS LESION NOTED. THE SPECIMEN IS SERIALY SECTIONED AND REPRESENTATIVE SECTION IS FROZEN. NO TUMOR SEEN IN THAT SECTION.

STATION 9 #1- NO TUMOR SEEN.

STATION 9 #2- NO TUMOR SEEN.

TISSUE ON PLEURAL SURFACE- STAPLED AREA MARKED WITH SUTURES BY THE SURGEON IS INKED AND SECTIONING SHOWS THAT THE TUMOR APPROACHES THE PLEURAL SURFACE, BUT DOES NOT PENETRATE IT.

RIGHT LOWER LOBE MASS- ADENOCARCINOMA.

STATION 7 #2- NO TUMOR SEEN.

Case Clinical Information

WELL DIFFERENTIATED ADENOCARCINOMA OF RLL
EGFR AND KRAS REQUESTED

Gross Description

A. Received in formalin labeled with the patient's name and "4R #1-FS" are three anthracotic tissues measuring up to 1.5 x 0.5 x 0.2 cm. The specimen is totally submitted in A1.

B. Received in formalin labeled with the patient's name and "4R #2-FS" is an anthracotic tissue measuring 1 x 0.5 x 0.1 cm.

Totally submitted in B1.

Prepared

[page 4 of 7]
C. Received in formalin labeled with the patient's name and "4R #3-FS" are six fragments of focally anthracotic yellow/tan soft tissue measuring up to 5 x 3 x 1 mm. The specimen is submitted totally wrapped in C1. [REDACTED]

D. Received in formalin labeled with the patient's name and "station 10-FS" are four focally anthracotic yellow/tan tissues measuring up to 5 x 3 x 1 mm. All material totally wrapped in D1. [REDACTED]

E. Received in formalin labeled with the patient's name and "station 7-FS" is a yellow/tan tissue measuring 2 x 1 x 0.5 mm. The specimen is totally submitted wrapped in E1. [REDACTED]

F. Received in formalin labeled with the patient's name and "wedge resection-NFS" is a wedge resection specimen measuring 9.5 x 2.5 x 1.5 cm. A 12 cm staple line extends along one aspect of the specimen. The staple line is removed and the freshly exposed surface is lightly inked blue. The pleural aspect appears shiny smooth and intact. The specimen has been previously, partially serially sectioned demonstrating minimal subtle induration without a discrete mass. The entire specimen is submitted in F1-F10. [REDACTED]

G. Received in formalin labeled with the patient's name and "wedge resection-FS" is a yellow/tan tissue measuring 2 x 1.5 x 0.2 cm. Totally submitted in G1. [REDACTED]

H. Received in formalin labeled with the patient's name and "level 9 #1-FS" is a brown/tan tissue measuring 1.1 x 0.5 x 0.2 cm thick. Totally submitted in H1. [REDACTED]

I. Received in formalin labeled with the patient's name and "level 9 #2" is a yellow/tan soft tissue measuring 2 x 1 x 0.2 cm thick. Totally submitted in I1. [REDACTED]

J. Received in formalin labeled with the patient's name and "level 7 #3-NFS" are two anthracotic yellow/tan tissues measuring up to 1.2 x 0.8 x 0.3 cm. Totally submitted in J1. [REDACTED]

K. Received in formalin labeled with the patient's name and "right lower lobe" is a specimen weighing 350 grams and measures 13 x 12 x 9 cm in greatest dimension. The hilar aspect has been previously inked black and sectioned perpendicular to the inked surface exposing a hilar tumor. In addition, the inferior aspect of the lung reveals an irregular adherent soft tissue fragment measuring 2 x 1 cm consistent with portion of diaphragm. The hilar aspect reveals several staple lines along hilar, vascular and airway structures. The staple lines are removed and the freshly exposed surfaces are lightly inked blue. The attached fragment of diaphragm is also inked blue. Subsequent sectioning reveals the presence of an ill-define area of induration measuring 4 x 4 x 2 cm in greatest dimension extending from close to the previously inked and partially dissected surface toward the previously described diaphragmatic adhesion. Adjacent lung appears diffusely somewhat indurated

Prep [REDACTED]

[page 5 of 7]
aswell. Section code: K1-K5= extensive sampling of apparent tumor in relationship to previously inked and partially sectioned surface; K6-K7= apparent diaphragmatic adhesion blocked out and totally submitted; K8-K10= shave hilar aspect after removing staple lines demonstrating vascular and airway structures together with possible lymphoid elements; K11-K18= extensive sampling from epicenter of apparent tumor not to include resection margins; K19-K20= interface of apparent tumor and adjacent indurated lung. [REDACTED]

L. Received in formalin labeled with the patient's name and "right lower lobe mass-FS" are four yellow/tan tissues measuring up to 2 x 1 x 0.2 cm thick. The specimen is submitted totally in L1. [REDACTED]

M. Received in formalin labeled with the patient's name and "station 7 #2-FS" is an anthracotic yellow/tan tissue measuring 2.5 x 1.5 x 0.3 cm. The specimen is submitted totally in M1. [REDACTED]

N. Received in formalin labeled with the patient's name and "tissue on pleural surface abutting middle lobe-FS" is a focally anthracotic yellow/tan tissue measuring 5 x 2 x 1 mm thick. Submitted totally wrapped in N1. [REDACTED]

Signed Supplemental

K. BLOCK K19 WAS SENT TO CLARIENT FOR KRAS AND EGFR MUTATION ANALYSIS. THE RESULTS ARE AS FOLLOWS:

KRAS MUTATION DETECTED.

GENOTYPE: MUTATION GLY12CYS (GGT->TGT)

NO EGFR ALTERATION DETECTED.

GENOTYPE: WILD-TYPE (NO EGFR ALTERATION DETECTED)

THE FULL REPORT FROM CLARIENT IS ON FILE IN THE PATHOLOGY DEPARTMENT.

Procedure

A. AA ROUTINE H&E X1 BLOCK

H&E X1

B. AA ROUTINE H&E X1 BLOCK

H&E X1

[page 6 of 7]
C. AA ROUTINE H&E X1 BLOCK
H&E X1
D. AA ROUTINE H&E X1 BLOCK
H&E X1
E. AA ROUTINE H&E X1 BLOCK
H&E X1
F. AA ROUTINE H&E X1 BLOCK.1
H&E X1
F. AA ROUTINE H&E X1 BLOCK.2
H&E X1
F. AA ROUTINE H&E X1 BLOCK.3
H&E X1
F. AA ROUTINE H&E X1 BLOCK.4
H&E X1
F. AA ROUTINE H&E X1 BLOCK.5
H&E X1
F. AA ROUTINE H&E X1 BLOCK.6
H&E X1
F. AA ROUTINE H&E X1 BLOCK.7
H&E X1
F. AA ROUTINE H&E X1 BLOCK.8
H&E X1
F. AA ROUTINE H&E X1 BLOCK.9
H&E X1
F. AA ROUTINE H&E X1 BLOCK.10
H&E X1
G. AA ROUTINE H&E X1 BLOCK
H&E X1
H. AA ROUTINE H&E X1 BLOCK
H&E X1
I. AA ROUTINE H&E X1 BLOCK
H&E X1
J. AA ROUTINE H&E X1 BLOCK
H&E X1
K. AA ROUTINE H&E X1 BLOCK.1
H&E X1 ELAST
K. AA ROUTINE H&E X1 BLOCK.2
H&E X1
K. AA ROUTINE H&E X1 BLOCK.3
H&E X1
K. AA ROUTINE H&E X1 BLOCK.4
H&E X1
K. AA ROUTINE H&E X1 BLOCK.5
H&E X1
K. AA ROUTINE H&E X1 BLOCK.6
H&E X1
K. AA ROUTINE H&E X1 BLOCK.7
H&E X1 ELAST
K. AA ROUTINE H&E X1 BLOCK.8

[page 7 of 7]
H&E X1
K. AA ROUTINE H&E X1 BLOCK.9
H&E X1
K. AA ROUTINE H&E X1 BLOCK.10
H&E X1
K. AA ROUTINE H&E X1 BLOCK.11
H&E X1
K. AA ROUTINE H&E X1 BLOCK.12
H&E X1
K. AA ROUTINE H&E X1 BLOCK.13
H&E X1
K. AA ROUTINE H&E X1 BLOCK.14
H&E X1
K. AA ROUTINE H&E X1 BLOCK.15
H&E X1
K. AA ROUTINE H&E X1 BLOCK.16
H&E X1
K. AA ROUTINE H&E X1 BLOCK.17
H&E X1
K. AA ROUTINE H&E X1 BLOCK.18
H&E X1
K. AA ROUTINE H&E X1 BLOCK.19
H&E X1
K. AA ROUTINE H&E X1 BLOCK.20
H&E X1
L. AA ROUTINE H&E X1 BLOCK
H&E X1
M. AA ROUTINE H&E X1 BLOCK
H&E X1
N. AA ROUTINE H&E X1 BLOCK
H&E X1

Source: NCI Genomic Data Commons file 814fe862-1757-4ea6-8864-a8acb0286961 (TCGA-J2-8194.9604F23F-F09C-480E-828F-5760B5FCDAE4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).